TCGA case TCGA-28-2512 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ca9c0f2-1be9-4376-aa27-d9db948d3f68

Demographics
Sex at birth: male; Race: white; Age at index: 37 years; Vital status: Dead; Days to death: 343 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 37.4 years (13,664 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 150 days; Days to treatment end: 150 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Number of cycles: 2.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 37.9 years (13,857 days); Days to diagnosis: 193 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 193 (post initial treatment): Progression or recurrence: Yes; Days to progression: 193 days.
- Days to follow up: 343 days; Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-2512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.4; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-28-2512-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-28-2512-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-28-2512-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: Recurrence.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Radiation treatment: Radiation type other: Gamma Knife; Therapy regimen: Recurrence; Therapy regimen other: No other infromation available.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 343 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 343 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 193 days.
